Somatic mutation profile of tumor specimen 0DZEHL from CCDI case PBCTEJ, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Synovial sarcoma, NOS; Tissue or organ of origin: Other ill-defined sites; Age at diagnosis: 15.1 years (5,507 days).
Specimen 0DZEHL: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 88f68a9e-df6b-46b2-bfa3-d30c3be1ff39.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DZEGX (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/eeff574a-39e6-407b-a689-fefb4f08afd6

The open-access MAF lists 11 somatic variants for this specimen: 6 protein-altering or splice-affecting, 2 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5, Silent 2, 3'UTR 1, Nonsense Mutation 1, 5'UTR 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AMPD2 | c.2215G>A p.D739N | Missense Mutation (SNP) | VAF 173/807 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM138144; called by muse, mutect2, varscan2
- GPAM | c.1646C>G p.T549S | Missense Mutation (SNP) | VAF 28/1018 reads (3%) | SIFT tolerated (0.51); PolyPhen benign (0.192); catalogued as rs1342077650; called by muse, mutect2
- NELL1 | c.190G>A p.E64K | Missense Mutation (SNP) | VAF 351/812 reads (43%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as rs1443891902; called by muse, mutect2, varscan2
- ADGB | c.424G>T p.E142* | Nonsense Mutation (SNP) | VAF 175/791 reads (22%) | called by muse, mutect2, varscan2
- CACNA2D1 | c.1489A>G p.I497V | Missense Mutation (SNP) | VAF 92/1030 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.549); called by muse, mutect2
- RNF141 | c.307T>G p.F103V | Missense Mutation (SNP) | VAF 363/882 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- DNAH8 | c.6498G>A p.Q2166= | Silent (SNP) | VAF 624/1422 reads (44%) | catalogued as COSV59489941; called by muse, mutect2, varscan2
- SPHKAP | c.3843C>T p.S1281= | Silent (SNP) | VAF 27/996 reads (3%) | catalogued as rs1203074370, COSV60884230; called by muse, mutect2
- C5orf15 | c.*69T>C | 3'UTR (SNP) | VAF 176/380 reads (46%) | called by muse, mutect2, varscan2
- GOLGA6L3 | n.717G>T | RNA (SNP) | VAF 37/208 reads (18%) | catalogued as rs372171595; called by muse, varscan2
- TUBB8 | c.-58G>A | 5'UTR (SNP) | VAF 70/266 reads (26%) | catalogued as rs1352110943; called by muse, mutect2
